Somatic mutation profile of tumor specimen MP2PRT-PAWBPC-TMP1-A (aliquot MP2PRT-PAWBPC-TMP1-A-1-0-D-A80M-36) from MP2PRT case MP2PRT-PAWBPC, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.7 years (622 days).
Specimen MP2PRT-PAWBPC-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d77d8df1-16d9-4252-8d05-b6b66ba47c88.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAWBPC-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAWBPC-NB1-A-1-0-D-A80M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0cfd5c79-fbd3-46d7-8fde-e1225da5d3a3

The open-access MAF lists 9 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 4, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GSG1 | c.205G>C p.A69P (on ENST00000651961 / NM_001080555.4; = p.A56P on NM_031289.5) | Missense Mutation (SNP) | VAF 141/481 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.047); catalogued as COSV100189266; called by muse, mutect2, varscan2
- SAMD4A | c.1748C>T p.T583M | Missense Mutation (SNP) | VAF 227/627 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.908); catalogued as rs948578399, COSV51888319; called by muse, mutect2, varscan2
- SEMA6D | c.333A>T p.K111N | Missense Mutation (SNP) | VAF 167/426 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TMX3 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ABHD8 | c.687G>A p.A229= | Silent (SNP) | VAF 180/553 reads (33%) | catalogued as rs765364538, COSV53112521, COSV53112543; called by muse, mutect2, varscan2
- MID2 | c.12C>T p.S4= | Silent (SNP) | VAF 96/168 reads (57%) | called by muse, mutect2, varscan2
- PCK1 | c.642G>A p.P214= | Silent (SNP) | VAF 150/486 reads (31%) | catalogued as rs138176491; called by muse, mutect2
- TGOLN2 | c.1137C>T p.S379= | Silent (SNP) | VAF 129/449 reads (29%) | catalogued as COSV56406576; called by muse, mutect2, varscan2
- KCNQ1 | c.1514+3089C>A | Intron (SNP) | VAF 118/391 reads (30%) | catalogued as rs190531268; called by muse, mutect2, varscan2
